Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A3Y7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A3Y7-01A (Primary Tumor).

Procurement Date Laterality: Tumor Features: Pigmented, Tumor Extent: Tumor 2.01?4mm
with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, facial

ICD-O-3

Tumor size: 1.5 x 1 x 2 cm

melanoma, NOS 8720/3

Tumor features: Pigmented

Site: CQCF: Subcutaneous tissue,
face
C49.0

Satellite nodules: Present

Histologic type: Malignant melanoma

Path: Skin, Face

Histologic grade:

C44.3 7-16-12
RD

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Breslow thickness is 4 mm

Comments: None

ICD-O-3 Discrepancy		☒

cm

pw
5/24/12

Source: NCI Genomic Data Commons file a859f639-10f1-493f-b33f-4aaf611e6cd5 (TCGA-EB-A3Y7.E9D3A87B-37FB-4FAF-854F-373DE709EE14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).